Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A618, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A618-01A (Primary Tumor).

Tumor ID

Microscopic Description:

Sections demonstrate a hypercellular astrocytic neoplasm. The tumor is identified infiltrating cortical grey matter. The neoplastic cells demonstrate moderate to marked cytologic atypia. Many of the tumor cells demonstrate significant nuclear atypia, including hyperchromatic enlarged pleomorphic nuclei. The tumor cells demonstrate features consistent with gemistocytic differentiation, including abundant eosinophilic cytoplasm and nuclear p53 positivity. An occasional blood vessel demonstrates perivascular lymphocytes. Significant mitotic activity is not seen. The MIB-1 LI is 2.8%. Microvascular proliferation and necrosis are not seen.

Diagnosis:

Left Temporal Tumor

Anaplastic gemistocytic astrocytoma (WHO grade III)

CCF ICD-O-3
Astrocytoma, anaplastic 9401/3
path Astrocytoma, gemistocytic 9411/3
Site: CCF Supratentorial NOS C71.0
path Brain, temporal lobe C71.2
JW 4/16/13

PIVAA Discrepancy		
Dual/Synchronous Primary M-tcd		

Source: NCI Genomic Data Commons file 30c7ea8d-b633-4830-ab11-3b39949d4ff5 (TCGA-HT-A618.1E45E711-0DF2-43BD-8E84-888813B93769.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).